Somatic mutation profile of tumor specimen TCGA-E1-A7YK-01A (aliquot TCGA-E1-A7YK-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YK, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.7 years (19,236 days).
Specimen TCGA-E1-A7YK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89f88ee9-af28-4467-ab2d-0dd3048ec56e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YK-10A (Blood Derived Normal), aliquot TCGA-E1-A7YK-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/288f1cff-d548-4962-93d4-b16e6f038a1f

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Splice Site 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 12/17 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.1313A>G p.K438R | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.353); catalogued as COSV99533141; called by muse, mutect2, varscan2
- AL645922.1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199946097, COSV54959295; called by muse, mutect2, varscan2
- ANAPC1 | c.105G>C p.L35F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100594861, COSV61975651; called by muse, mutect2
- ARHGAP5 | c.3170A>C p.N1057T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV100565182; called by muse, mutect2, varscan2
- ATF6B | c.966+2T>C p.X322_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100916839; called by muse, mutect2, varscan2
- ATRX | c.4895T>C p.L1632S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100971065; called by muse, varscan2
- ATRX | c.4835T>C p.L1612P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100971068; called by muse, varscan2
- AXL | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996780; called by muse, mutect2
- BHLHE40 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1226009039, COSV99848195; called by muse, mutect2, varscan2
- BRCA2 | c.5435A>G p.E1812G | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.199); catalogued as COSV101204415; called by muse, mutect2, varscan2
- CDCP1 | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99944135; called by muse, mutect2, varscan2
- CYP2C18 | c.907A>G p.S303G | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV99608669; called by muse, mutect2, varscan2
- DNAH3 | c.736A>T p.M246L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV99768509; called by muse, mutect2, varscan2
- ENGASE | c.465G>T p.W155C | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158294280, COSV100285858; called by muse, mutect2, varscan2
- FAM47A | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.731); catalogued as rs764031941, COSV60495676, COSV60499390; called by muse, mutect2
- FLG2 | c.4784G>A p.R1595Q | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated (0.59); catalogued as rs201802558, COSV101165639, COSV66167043; called by muse, mutect2, varscan2
- FOXA1 | c.1322G>C p.S441T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.048); catalogued as COSV99163539; called by muse, mutect2
- GUF1 | c.526G>C p.V176L | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.475); catalogued as COSV99877353; called by muse, mutect2, varscan2
- IL18R1 | c.351C>G p.H117Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99295283; called by muse, mutect2
- ITGB4 | c.2884G>T p.V962L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV99564273; called by muse, mutect2, varscan2
- KCNK2 | c.193A>G p.I65V (on ENST00000444842 / NM_001017425.3; = p.I50V on NM_014217.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV101222231; called by muse, mutect2
- LRP3 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1221559321, COSV99473339; called by muse, mutect2, varscan2
- MYEF2 | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99981801; called by muse, mutect2, varscan2
- NEBL | c.1592T>G p.I531S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as COSV101009266; called by muse, mutect2
- NETO1 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100199031; called by muse, mutect2, varscan2
- OR14J1 | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101012805; called by muse, mutect2, varscan2
- RALGAPA1 | c.3949G>C p.A1317P | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99355259; called by muse, mutect2
- RYR1 | c.7229C>T p.P2410L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as rs145787667, COSV100616972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100A9 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs142015410; called by muse, mutect2, varscan2
- SLC17A4 | c.554A>C p.Y185S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100930633; called by muse, mutect2
- SPTB | c.5937+1G>A p.X1979_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV101072243; called by muse, varscan2
- STAMBP | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV100277728; called by muse, mutect2
- THRB | c.938T>G p.M313R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CM961369, COSV99769572; called by muse, mutect2, varscan2
- TMTC4 | c.2098G>T p.G700* (on ENST00000376234 / NM_001350577.2; = p.G719* on NM_032813.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | catalogued as COSV100168770; called by muse, mutect2, varscan2
- TTN | c.50662G>C p.V16888L (on ENST00000591111; = p.V9464L on NM_003319.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | PolyPhen possibly damaging (0.574); catalogued as COSV100619044, COSV60247457; called by muse, mutect2, varscan2
- USP12 | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99997674; called by muse, mutect2
- ZEB2 | c.3446G>C p.G1149A | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV100356362; called by muse, mutect2
- ZNF304 | c.1477C>A p.H493N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV99988697; called by muse, mutect2
- ZNF343 | c.267A>C p.E89D | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as COSV99601487; called by muse, mutect2, varscan2
- ACAN | c.1779A>G p.E593= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100718489; called by muse, mutect2, varscan2
- DRAM2 | c.114G>A p.P38= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs757484526, COSV99713419; called by muse, mutect2, varscan2
- GRHL3 | c.861C>T p.F287= (on ENST00000350501 / NM_198174.3; = p.F292= on NM_021180.3) | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV52567899; called by muse, mutect2
- KDR | c.2658C>G p.L886= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV55772789; called by muse, mutect2, varscan2
- LRP2 | c.6228T>C p.F2076= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV99786952; called by muse, mutect2, varscan2
- RTL8B | c.117G>A p.R39= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs1263966327, COSV101195607; called by muse, mutect2, varscan2
- SIN3B | c.1305C>T p.D435= | Silent (SNP) | VAF 50/302 reads (17%) | catalogued as rs771385129, COSV99931748; called by muse, mutect2, varscan2
- TRPM3 | c.1848A>G p.T616= (on ENST00000357533 / NM_001366142.2; = p.T459= on NM_020952.6) | Silent (SNP) | VAF 25/277 reads (9%) | catalogued as COSV100677754; called by muse, mutect2
- TUT4 | c.4761T>C p.R1587= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99932524; called by muse, mutect2
- ZBED9 | c.3609T>C p.N1203= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV101509298; called by muse, mutect2
- MGAM | c.4618+1893C>T | Intron (SNP) | VAF 9/45 reads (20%) | catalogued as COSV101527564; called by muse, mutect2, varscan2
